Gene-level copy-number profile of tumor specimen TCGA-2Y-A9H6-01A from TCGA case TCGA-2Y-A9H6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.4 years (24,982 days).
Specimen TCGA-2Y-A9H6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.7a026bc0-e87d-421c-9e6e-25cce747ed90.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9H6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b735e834-b13e-411f-af41-19e7ad903b00

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 11,437; copy number 2: 43,875; copy number 3: 4,109; copy number 4: 103; copy number 5: 183; copy number 6: 5; copy number 7: 2; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9H6-01A-11D-A38W-01): tumor purity 0.67, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–6,885,276, 94 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:16,726,814–17,503,923, 9 genes: BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr9:17,589,161–17,591,318, 1 gene: PABPC1P11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 189 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,998,651–162,812,817, 122 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:162,824,795–162,849,467, 1 gene, copy number 5 (within-gene range 3–5): AL392003.2.
- chr1:188,218,400–188,732,208, 6 genes, copy number 5: AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1.
- chr1:213,492,288–213,988,508, 4 genes, copy number 6 (within-gene range 3–6): AL592402.1, AC096639.1, PROX1-AS1, LINC00538.
- chr1:223,144,049–224,035,056, 18 genes, copy number 5: AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2.
- chr3:30,292,548–31,269,406, 13 genes, copy number 5: AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11.
- chr4:10,006,482–10,295,579, 15 genes, copy number 5: SLC2A9-AS1, AC005674.1, WDR1, MIR3138, RNA5SP155, AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,216,416–77,216,878, 1 gene, copy number 6: AC008638.3.
- chr5:121,671,373–121,852,833, 2 genes, copy number 5: AC106806.2, FTMT.
- chr6:91,557,292–91,690,428, 1 gene, copy number 9 (within-gene range 3–9): CASC6.
- chr8:139,108,430–139,127,953, 2 genes, copy number 7: AC100807.1, AC100807.2.
- chr12:114,077,133–114,113,489, 4 genes, copy number 5: AC010183.1, AC010183.2, HAUS8P1, GLULP5.

Autosomal genes at a single copy (total copy number 1): 11,365. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
